Somatic mutation profile of tumor specimen C3L-09066-02 (aliquot CPT0514990006) from CPTAC case C3L-09066, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.2 years (23,803 days).
Specimen C3L-09066-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c247cef7-f2af-44af-bb7c-ef151c8a7657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09066-31 (Blood Derived Normal), aliquot CPT0515130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e935217-f1b5-4e32-a42c-ee21697e608c

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 24, Nonsense Mutation 9, Intron 3, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs66527965, CM910082, CM920201; ClinVar: pathogenic; called by muse, mutect2
- ACCS | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV55459060; called by muse, mutect2
- ADGRG4 | c.3334C>T p.H1112Y | Missense Mutation (SNP) | VAF 16/413 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99795340; called by muse, mutect2
- AFF2 | c.2603A>C p.K868T | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53975964, COSV53982508; called by muse, mutect2
- ALK | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.251); catalogued as rs774004991, COSV66560581; ClinVar: uncertain significance; called by muse, varscan2
- AMOT | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 20/542 reads (4%) | catalogued as COSV59062227; called by muse, mutect2
- CCDC166 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 20/690 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as rs1554616603, COSV101545854; called by muse, mutect2
- CDH16 | c.2159C>T p.T720I | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV55336020; called by muse, mutect2
- CPNE3 | c.778del p.S260Afs*10 | Frame Shift Del (DEL) | VAF 34/279 reads (12%) | catalogued as rs761955273; called by mutect2, pindel, varscan2
- CYLC1 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1358418612, COSV61415383; called by muse, mutect2
- DKC1 | c.1181A>G p.K394R | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV101053812, COSV101053836; called by muse, mutect2
- EBF2 | c.1468T>G p.L490V | Missense Mutation (SNP) | VAF 31/395 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1156879434, COSV68778596, COSV68780628; called by muse, mutect2
- F8 | c.2428T>G p.L810V | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV64272502; called by muse, mutect2
- GABRA4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 17/318 reads (5%) | catalogued as COSV51935151; called by muse, mutect2
- IQSEC3 | c.1037G>A p.R346H (on ENST00000538872 / NM_001170738.2; = p.R43H on NM_015232.1) | Missense Mutation (SNP) | VAF 25/551 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs782058255, COSV58285616; called by muse, mutect2
- IRS1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 18/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305808839; called by muse, mutect2
- IRX6 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 57/547 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555631263; called by muse, mutect2
- KCNH5 | c.2288C>T p.T763M | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs1181303550, COSV59757551; called by muse, mutect2
- KRTAP13-4 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.989); catalogued as COSV61879350; called by muse, mutect2
- LIN7A | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 14/419 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1318199370, COSV54019496; called by muse, mutect2
- LRRC53 | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs919963650, COSV53949995; called by muse, mutect2
- MAGEC2 | c.828A>C p.K276N | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV55997644, COSV99909877; called by muse, mutect2
- MUC17 | c.10180C>G p.P3394A | Missense Mutation (SNP) | VAF 12/431 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60283542; called by muse, mutect2
- NAPRT | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 33/728 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs148205878; called by muse, mutect2
- NOX4 | c.388T>G p.F130V | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV99629212, COSV99629676; called by muse, mutect2
- PRAMEF4 | c.1104A>C p.Q368H | Missense Mutation (SNP) | VAF 40/720 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs369619869; called by muse, mutect2
- PROB1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 38/716 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as rs1176137586, COSV100130230; called by muse, mutect2
- PTPRF | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs1343911174; called by muse, mutect2
- SLC8A2 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 15/505 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1343684976; called by muse, mutect2
- SLITRK2 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 28/547 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59429090; called by muse, mutect2
- SULF1 | c.1029T>A p.F343L | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.127); catalogued as rs1393389615, COSV52672077; called by muse, mutect2
- SV2A | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781926005, COSV64965949; called by muse, mutect2
- TCEAL6 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 33/753 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1473915769, COSV65654109; called by muse, mutect2
- TEX13A | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 19/520 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs782474353; called by muse, mutect2
- TMEM132C | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs999891946; called by muse, mutect2
- ZNF292 | c.6343C>T p.R2115* | Nonsense Mutation (SNP) | VAF 21/387 reads (5%) | catalogued as rs866467799, COSV60535418; called by muse, mutect2
- ZNF354C | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100203747; called by muse, mutect2
- ZNF585A | c.761A>C p.K254T (on ENST00000292841 / NM_001288800.2; = p.K199T on NM_152655.3) | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); catalogued as COSV53064827, COSV99492776; called by muse, mutect2
- ZNF599 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100251350; called by muse, mutect2
- ADCY8 | c.1880T>C p.L627P | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ANO4 | c.798C>A p.H266Q (on ENST00000392977 / NM_001286615.2; = p.H231Q on NM_178826.4) | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CCDC141 | c.3085A>G p.S1029G | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- CDH2 | c.1730C>A p.A577D | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDHR5 | c.1167C>G p.D389E | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- CDNF | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- CDV3 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 14/385 reads (4%) | called by muse, mutect2
- CEP350 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.328); called by muse, mutect2
- CPE | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); called by muse, mutect2
- CSNKA2IP | c.1378A>G p.R460G | Missense Mutation (SNP) | VAF 9/298 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2
- CYLC2 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.061); called by muse, mutect2
- FHOD1 | c.3068G>C p.G1023A | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.146); called by muse, mutect2
- FRMD4A | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- GAB2 | c.909C>A p.C303* (on ENST00000361507 / NM_080491.3; = p.C265* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 24/509 reads (5%) | called by muse, mutect2
- HTATSF1 | c.1394A>C p.K465T | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- KLHL34 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 23/509 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- LINC02218 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 12/375 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2
- LRP10 | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.393); called by muse, mutect2
- MAPK8IP1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 12/602 reads (2%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2
- MNX1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- MPP1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2
- MYCBP2 | c.7372A>C p.K2458Q (on ENST00000357337; = p.K2496Q on NM_015057.5) | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- NBEA | c.7723A>T p.S2575C | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- NCOA3 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- OCA2 | c.1958T>G p.I653S | Missense Mutation (SNP) | VAF 7/226 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2
- OR5T2 | c.1011A>C p.K337N | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- OR5T3 | c.867T>G p.F289L | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); called by muse, mutect2
- PHF8 | c.1886C>A p.A629E (on ENST00000357988 / NM_001184896.1; = p.A593E on NM_015107.3) | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.047); called by muse, mutect2
- PLCL1 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 8/256 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- PRLHR | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 24/577 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSG1 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); called by muse, mutect2
- RGS19 | c.152G>A p.W51* | Nonsense Mutation (SNP) | VAF 14/330 reads (4%) | called by muse, mutect2
- ROR2 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.28); called by muse, mutect2
- SAMD9 | c.2828G>A p.G943E | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.335); called by muse, mutect2
- SEMA6A | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2
- SUSD5 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- TEX13C | c.2015A>C p.K672T | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TLL1 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2
- TRIM42 | c.950T>C p.F317S | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2
- TRIM67 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 24/648 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2
- TRPC4 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 14/371 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- USP17L7 | c.1480C>G p.P494A | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- UTP14A | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); called by muse, mutect2
- WNT5A | c.185T>G p.I62S | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ZFP28 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 14/357 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2
- ZMYM2 | c.3499G>T p.G1167* | Nonsense Mutation (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- ZNF432 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- ZNF534 | c.397T>C p.W133R (on ENST00000332323 / NM_001143939.3; = p.W120R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2
- ZNF730 | c.340A>G p.R114G | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- BTBD8 | c.2427T>C p.T809= (on ENST00000636805 / NM_001376131.1; = p.T296= on NM_015237.4) | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs909403191; called by muse, mutect2
- CASR | c.789G>A p.T263= | Silent (SNP) | VAF 28/472 reads (6%) | catalogued as rs369124816, COSV56142135; ClinVar: uncertain significance; called by muse, mutect2
- CCDC88B | c.786C>T p.N262= | Silent (SNP) | VAF 15/433 reads (3%) | called by muse, mutect2
- CDH18 | c.346C>T p.L116= | Silent (SNP) | VAF 15/476 reads (3%) | catalogued as COSV56920213; called by muse, mutect2
- CDK13 | c.3990G>A p.V1330= | Silent (SNP) | VAF 18/404 reads (4%) | catalogued as rs1460281538; called by muse, mutect2
- CLEC14A | c.564T>C p.S188= | Silent (SNP) | VAF 20/577 reads (3%) | called by muse, mutect2
- DNAH10 | c.6333T>C p.P2111= (on ENST00000409039; = p.P2050= on NM_207437.3) | Silent (SNP) | VAF 24/544 reads (4%) | called by muse, mutect2
- EIF2A | c.114T>C p.N38= | Silent (SNP) | VAF 11/264 reads (4%) | catalogued as rs1208239956; called by muse, mutect2
- FAM181B | c.993G>A p.P331= | Silent (SNP) | VAF 27/634 reads (4%) | catalogued as rs1370436626; called by muse, mutect2
- IGFBP1 | c.63C>T p.G21= | Silent (SNP) | VAF 34/500 reads (7%) | called by muse, mutect2
- ITIH6 | c.153C>T p.A51= | Silent (SNP) | VAF 17/543 reads (3%) | called by muse, mutect2
- L3MBTL4 | c.1860A>G p.E620= | Silent (SNP) | VAF 23/263 reads (9%) | catalogued as COSV53112649; called by muse, mutect2
- LENG8 | c.1158G>A p.G386= | Silent (SNP) | VAF 44/720 reads (6%) | catalogued as rs577399483; called by muse, mutect2
- LRMDA | c.66C>T p.S22= | Silent (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- MPDZ | c.5337C>T p.D1779= | Silent (SNP) | VAF 26/376 reads (7%) | catalogued as rs763697590, COSV100057011; called by muse, mutect2
- MUC16 | c.4254T>C p.S1418= | Silent (SNP) | VAF 19/476 reads (4%) | catalogued as rs1397902741; called by muse, mutect2
- NIN | c.3420G>A p.R1140= | Silent (SNP) | VAF 26/438 reads (6%) | called by muse, mutect2
- OR1K1 | c.933C>A p.I311= | Silent (SNP) | VAF 10/241 reads (4%) | catalogued as COSV99474168; called by muse, mutect2
- PCDH9 | c.2749A>C p.R917= | Silent (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- PRAMEF20 | c.439T>C p.L147= | Silent (SNP) | VAF 17/400 reads (4%) | called by muse, mutect2
- SPTB | c.2574C>T p.D858= | Silent (SNP) | VAF 20/486 reads (4%) | catalogued as rs1293691630, COSV101072344; called by muse, mutect2
- TNS2 | c.2487C>T p.G829= (on ENST00000314250 / NM_170754.4; = p.G839= on NM_015319.2) | Silent (SNP) | VAF 22/535 reads (4%) | called by muse, mutect2
- TTN | c.16581T>G p.V5527= (on ENST00000591111; = p.V4600= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/362 reads (6%) | called by muse, mutect2
- USP27X | c.354C>T p.P118= | Silent (SNP) | VAF 24/530 reads (5%) | catalogued as rs781828784; called by muse, mutect2
- CBL | c.*6554G>A | 3'UTR (SNP) | VAF 25/400 reads (6%) | called by muse, mutect2
- CLEC7A | c.202+81A>G | Intron (SNP) | VAF 25/447 reads (6%) | called by muse, mutect2
- NAV3 | c.2024-12911G>A | Intron (SNP) | VAF 10/300 reads (3%) | catalogued as rs1350071736; called by muse, mutect2
- RNF227 | c.518-25C>T | Intron (SNP) | VAF 17/374 reads (5%) | called by muse, mutect2
